Surgical pathology report (de-identified scan), TCGA case TCGA-22-4609, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-4609-01A (Primary Tumor).

[REDACTED] Surgical Pathology

TISSUE DESCRIPTION:

Right upper lobe lung (250 grams, 21 x 13 x 4.8 cm) and superior (right lower paratracheal) and inferior mediastinal (subcarinal) and N1 (right hilar) lymph nodes

DIAGNOSIS:

Lung, right upper lobe, lobectomy: Invasive grade 3 (of 4) squamous cell carcinoma with central necrosis forming an ill-defined intrapulmonary nodule measuring 2 x 2 x 1.1 cm. The overlying pleura is not involved. The bronchial margin and one intrapulmonary peribronchial lymph node are negative for tumor. Organizing pneumonia is observed focally forming two separate nodules (0.5 cm).

Lymph nodes, superior and inferior mediastinal, N1, excision: Multiple superior (4 right lower paratracheal) and inferior mediastinal (6 subcarinal) and N1 (3 right hilar) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file 2c78cfbf-b985-4a11-8c3e-54e0813c92db (TCGA-22-4609.EB0D58DA-99C4-4B6A-B226-5F758AA59F6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).